CCDI case PBCTTS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/e07aec6b-1f90-4771-837b-f91bd70d2e09

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Retinoblastoma, diffuse: ICD-O-3 morphology code: 9513/3; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 6.3 years (2,290 days).

Biospecimens (3 samples)
- Sample 0DZHVW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DZRYP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DZRYU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
